Somatic mutation profile of tumor specimen MP2PRT-PANVJI-TMP1-A (aliquot MP2PRT-PANVJI-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PANVJI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.2 years (2,257 days).
Specimen MP2PRT-PANVJI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e9ee12c4-a6cb-4891-a379-c9e7d88e370f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANVJI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANVJI-NB1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec2df24d-7af9-4783-ba41-f1374c88bc42

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 2, Frame Shift Del 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RAD50 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 74/180 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370769989, COSV54748170; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ABCC12 | c.2522C>T p.A841V | Missense Mutation (SNP) | VAF 25/374 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs375186984; called by muse, mutect2
- ADGRB3 | c.940C>T p.R314* | Nonsense Mutation (SNP) | VAF 35/302 reads (12%) | catalogued as rs752634970, COSV65397795; called by muse, mutect2, varscan2
- GIPC2 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 82/261 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs143579527; called by muse, mutect2, varscan2
- NDST3 | c.1279G>A p.V427I | Missense Mutation (SNP) | VAF 139/300 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as rs150758016; called by muse, mutect2, varscan2
- ZC2HC1A | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs148584360; called by muse, mutect2, varscan2
- H2AC11 | c.331_357delinsT p.N111* | Frame Shift Del (DEL) | VAF 76/272 reads (28%) | called by pindel, varscan2*
- IGKJ2 | chr2:88861539 TTGGTCCCCTGGCCAAAACTGCACACACAATGG>CT | Missense Mutation (DEL) | VAF 24/48 reads (50%) | called by pindel, varscan2*
- FDPS | c.735C>T p.P245= | Silent (SNP) | VAF 123/303 reads (41%) | called by muse, mutect2, varscan2
- SLCO3A1 | c.1530G>A p.A510= | Silent (SNP) | VAF 16/290 reads (6%) | catalogued as rs375014073; called by muse, mutect2
- KCTD1 | c.-15-45928C>T | Intron (SNP) | VAF 158/330 reads (48%) | catalogued as rs1316586092; called by muse, mutect2, varscan2
